Gene-level copy-number profile of tumor specimen C3L-07985-01 from CPTAC case C3L-07985, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 69.1 years (25,239 days).
Specimen C3L-07985-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2cbd2f2-eb62-4637-9ed1-1280b9446094.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07985-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,070 have no estimate.
https://portal.gdc.cancer.gov/files/c2a32218-6c85-4b67-b244-31a3a2c3f0af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 175; copy number 1: 14,529; copy number 2: 33,513; copy number 3: 8,734; copy number 4: 832; copy number 5: 193; copy number 6: 229; copy number 7: 73; copy number 8: 25; copy number 9: 21; copy number 10: 22; copy number 11: 39; copy number 12: 59; copy number 13: 16; copy number 14: 28; copy number 15: 7; copy number 18: 2; copy number 21: 4; copy number 26: 12; copy number 27: 3; copy number 28: 4; copy number 29: 2; copy number 30: 5; copy number 33: 13; copy number 35: 10; copy number 51: 1; copy number 58: 2.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,456,909–8,582,655, 5 genes: AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr13:19,633,659–19,783,019, 4 genes (within-gene range 0–1): MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P.
- chr14:93,397,139–93,397,234, 1 gene (within-gene range 0–1): Y_RNA.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–1): BNIP3P22, AC008554.1, BNIP3P23.
- chr19:34,254,552–34,409,364, 5 genes (within-gene range 0–1): GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 770 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,727,117–31,764,893, 1 gene, copy number 5 (within-gene range 3–5): ADGRB2.
- chr1:234,527,887–235,128,837, 23 genes, copy number 5: LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B.
- chr6:36,493,892–36,675,270, 8 genes, copy number 5: STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2.
- chr6:43,450,352–44,089,696, 26 genes, copy number 5–9 (within-gene range 3–9): DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1.
- chr6:142,526,455–142,637,889, 1 gene, copy number 5: AL359313.1.
- chr7:2,474,844–2,775,500, 7 genes, copy number 5 (within-gene range 1–5): GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1.
- chr8:10,482,878–10,547,585, 1 gene, copy number 5 (within-gene range 1–5): PRSS51.
- chr8:10,525,532–12,071,747, 56 genes, copy number 5–11: PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B.
- chr8:12,310,962–12,359,391, 4 genes, copy number 13: DEFB130A, RNA5SP254, DEFB108E, ZNF705CP.
- chr8:29,067,278–29,263,124, 1 gene, copy number 5 (within-gene range 2–5): KIF13B.
- chr8:29,218,905–29,360,222, 4 genes, copy number 5–6: HMGB1P23, DUSP4, AC084262.2, AC084262.1.
- chr9:129,430,652–129,642,169, 10 genes, copy number 5: AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1.
- chr9:136,546,173–138,253,217, 109 genes, copy number 5–14 (broad region; genes not listed).
- chr10:17,577,362–18,940,953, 21 genes, copy number 7–13: PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1.
- chr10:19,812,372–21,497,260, 23 genes, copy number 5–8: AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675, NEBL, MTND1P21, AL157398.1, EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915.
- chr12:32,679,200–32,756,463, 9 genes, copy number 5: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2.
- chr17:20,999,596–21,043,760, 2 genes, copy number 5 (within-gene range 3–5): USP22, AC087393.2.
- chr17:72,290,091–72,640,472, 3 genes, copy number 5 (within-gene range 2–5): LINC00511, LINC02003, AC007639.1.
- chr19:27,638,483–28,970,874, 32 genes, copy number 26–58 (within-gene range 1–58): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2.
- chr19:29,606,283–30,713,538, 16 genes, copy number 27–33: POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr20:42,072,752–47,656,877, 164 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr20:53,255,979–54,269,542, 17 genes, copy number 15–28 (within-gene range 3–28): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.
- chr20:63,743,668–63,832,038, 1 gene, copy number 5 (within-gene range 4–7): ZBTB46.
- chr20:63,808,076–63,956,985, 16 genes, copy number 5–7 (within-gene range 2–7): ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr22:20,707,691–23,164,350, 215 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
